MMRF case MMRF_1803 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4e4989c0-f40e-4d8e-80c0-60d60e54e034

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.3 years (23,854 days); ISS stage: II; Days to last known disease status: 1,065 days (2.9 years); Days to last follow up: 1,065 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 143 days; Days to treatment end: 143 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 107 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 51.7 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 8.9 g/dL; Glucose 4.84 mmol/L.
- Day 81 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.775 mg/dL; Immunoglobulin G 40.6 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.17 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L.
- Day 175 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 12.6 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 1.93 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 8.14 mmol/L.
- Day 245 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.36 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 6.82 mmol/L.
- Day 324 (ECOG 1): M Protein 0.3 g/dL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.
- Day 449 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.85 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 1.05 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 512 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.08 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.39 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 4.24 mmol/L.
- Day 610 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.49 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 3.91 mmol/L.
- Day 694 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.34 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.83 mmol/L.
- Day 778 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.82 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 1.98 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 6.33 mmol/L.
- Day 890 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 3 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 7.26 mmol/L.
- Day 953 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.28 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 2.84 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.
- Day 1,065 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Immunoglobulin G 9.76 g/L; Immunoglobulin A 3.5 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -13: Weight: 84 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1803_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1803_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
